Somatic mutation profile of cancer-model specimen HCM-BROD-0485-C15-85M (3D Organoid, passage 5; aliquot HCM-BROD-0485-C15-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0485-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 46.5 years (16,967 days).
Specimen HCM-BROD-0485-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aaa99850-c458-4e6b-9b3a-2824524d3e4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0485-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0485-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c63c28a-12ec-4b03-b3af-cc00ac2c8f0f

The open-access MAF lists 185 somatic variants for this specimen: 139 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 39, Nonsense Mutation 4, Intron 3, Splice Region 3, Frame Shift Del 2, RNA 2, Nonstop Mutation 1, Frame Shift Ins 1, Translation Start Site 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC4A11 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 157/192 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121909388, CM063151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 106/229 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 261/261 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AFDN | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 141/141 reads (100%) | catalogued as COSV60041076; called by muse, mutect2, varscan2
- APOB | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 186/712 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); catalogued as rs371884333, COSV99265146; called by muse, mutect2, varscan2
- ARNT2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 162/316 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs765287094; called by muse, mutect2, varscan2
- ASB4 | c.1201C>A p.H401N | Missense Mutation (SNP) | VAF 22/696 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs1410370770; called by muse, mutect2
- ATG2B | c.5368G>A p.E1790K | Missense Mutation (SNP) | VAF 218/450 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV55890618; called by muse, mutect2, varscan2
- AURKB | c.550T>G p.L184V | Missense Mutation (SNP) | VAF 127/163 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs747492163; called by muse, mutect2, varscan2
- AZIN2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 190/417 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs374895105; called by muse, mutect2, varscan2
- CALD1 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 95/353 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV62645511; called by muse, mutect2, varscan2
- CATSPER2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 160/339 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376517321, COSV58660267; called by muse, mutect2, varscan2
- CDRT15L2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 166/336 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.833); catalogued as rs771538435; called by muse, mutect2, varscan2
- CFAP46 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 192/469 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs532867979; called by muse, mutect2, varscan2
- CILP2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 312/689 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1472767769, COSV52273486; called by muse, mutect2, varscan2
- CIPC | c.382T>G p.L128V | Missense Mutation (SNP) | VAF 165/386 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV62377248; called by muse, mutect2, varscan2
- CSH1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs779248131; called by muse, mutect2, varscan2
- CSH2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 271/1423 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs755600756, COSV100400231; called by muse, mutect2, varscan2
- CYFIP1 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 166/448 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs756767407; called by muse, mutect2, varscan2
- DENND6A | c.1353A>T p.L451F | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1338285827; called by muse, mutect2, varscan2
- DIP2A | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs766463257, COSV59473256; called by muse, mutect2
- EBF2 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 316/512 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV101282264; called by muse, mutect2, varscan2
- FAM187B | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1389739363; called by muse, mutect2
- FAM234A | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 261/571 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as rs774996392, COSV51452809; called by muse, mutect2, varscan2
- FAM240B | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.773); catalogued as rs975294952; called by muse, mutect2
- FAT4 | c.8657T>G p.L2886R | Missense Mutation (SNP) | VAF 137/280 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58674921, COSV58711887; called by muse, mutect2, varscan2
- HAT1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 107/317 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs368462108; called by muse, mutect2, varscan2
- HCN4 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758468167, COSV56084416, COSV99984381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ICE1 | c.3645A>G p.I1215M | Missense Mutation (SNP) | VAF 140/344 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.234); catalogued as rs762694872; called by muse, mutect2, varscan2
- KCTD4 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 120/138 reads (87%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.277); catalogued as rs562563207, COSV61242345; called by muse, mutect2, varscan2
- KHDRBS3 | c.7_9del p.E3? | Translation Start Site (DEL) | VAF 178/806 reads (22%) | catalogued as rs775225910; called by pindel, varscan2
- KLHL40 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 92/733 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs1310855261; called by muse, mutect2, varscan2
- MRNIP | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 254/600 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs562422912, COSV52975381; called by muse, mutect2
- MYF6 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 141/336 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57351550; called by muse, mutect2, varscan2
- OR4C15 | c.188A>G p.E63G (on ENST00000314644; = p.E9G on NM_001001920.2) | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV58951804, COSV58951861; called by muse, mutect2, varscan2
- PCDH19 | c.2508G>C p.E836D (on ENST00000373034 / NM_001184880.2; = p.E789D on NM_020766.3) | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.385); catalogued as COSV55263636; called by muse, mutect2, varscan2
- PDLIM1 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 94/293 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1201013714; called by muse, mutect2, varscan2
- PDXP | c.362_373del p.E121_A124del | In Frame Del (DEL) | VAF 175/504 reads (35%) | catalogued as rs897458816; called by mutect2, varscan2
- PKD1 | c.2512G>A p.V838M | Missense Mutation (SNP) | VAF 339/674 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.406); catalogued as rs764575507; called by muse, mutect2, varscan2
- PROS1 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 254/410 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM163572, CM951040, COSV62399187; called by muse, mutect2, varscan2
- RYR1 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372460800; called by muse, mutect2, varscan2
- SEC24B | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 138/368 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as rs199826133, COSV99493536; called by muse, mutect2, varscan2
- SEPTIN8 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 57/556 reads (10%) | catalogued as COSV51523690; called by muse, mutect2, varscan2
- SHANK1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 356/741 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954426144; called by muse, mutect2, varscan2
- SLC22A7 | c.1066G>A p.G356R (on ENST00000372585 / NM_153320.2; = p.G354R on NM_006672.3) | Missense Mutation (SNP) | VAF 155/155 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1205738663; called by muse, mutect2, varscan2
- SMARCA4 | c.4805A>C p.K1602T | Missense Mutation (SNP) | VAF 209/250 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1485676007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SSH3 | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 250/652 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1371698874; called by muse, mutect2, varscan2
- TBC1D2 | c.2656C>T p.R886W (on ENST00000465784 / NM_001267571.2; = p.R875W on NM_018421.4) | Missense Mutation (SNP) | VAF 258/512 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs753913278, COSV59784403, COSV59789580; called by muse, varscan2
- TEX13C | c.2534A>G p.K845R | Missense Mutation (SNP) | VAF 219/221 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV101084795; called by muse, mutect2, varscan2
- TLN2 | c.6143C>T p.A2048V | Missense Mutation (SNP) | VAF 54/710 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137970385, COSV60890419; called by muse, mutect2
- TM9SF2 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs372811557; called by muse, mutect2, varscan2
- WIZ | c.5131C>T p.R1711C (on ENST00000673675 / NM_001371589.1; = p.R616C on NM_021241.3) | Missense Mutation (SNP) | VAF 345/1864 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1312221467, COSV99652657; called by muse, mutect2, varscan2
- ZBTB7C | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 170/1250 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as rs549734487; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1311A>C p.K437N | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56271980; called by muse, mutect2, varscan2
- ZNF568 | c.1749A>C p.K583N | Missense Mutation (SNP) | VAF 142/178 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101426849, COSV71278656, COSV71279101; called by muse, mutect2
- ZNF717 | c.297C>A p.D99E | Missense Mutation (SNP) | VAF 96/473 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as rs1420738328; called by muse, mutect2
- ASXL3 | c.4319A>C p.N1440T | Missense Mutation (SNP) | VAF 345/559 reads (62%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAHD1 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 248/611 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- BTBD8 | c.5179T>C p.Y1727H (on ENST00000636805 / NM_001376131.1; = p.Y1214H on NM_015237.4) | Missense Mutation (SNP) | VAF 115/251 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD4D | c.247_248del p.P83Sfs*273 | Frame Shift Del (DEL) | VAF 292/934 reads (31%) | called by mutect2, pindel, varscan2
- CARM1 | c.668A>C p.E223A | Missense Mutation (SNP) | VAF 117/142 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CCDC141 | c.3505A>T p.I1169F | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- CDH10 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 131/363 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CENPE | c.790_791insG p.I264Sfs*10 | Frame Shift Ins (INS) | VAF 101/297 reads (34%) | called by mutect2, pindel, varscan2
- CFAP54 | c.7378-1G>C p.X2460_splice | Splice Site (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- CFH | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL4A3 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.229); called by muse, mutect2
- CPNE2 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 148/394 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, varscan2
- DACH2 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DENND6A | c.1408A>G p.S470G | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DSEL | c.1826G>A p.S609N | Missense Mutation (SNP) | VAF 183/338 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DYNC2I1 | c.3038A>G p.K1013R | Missense Mutation (SNP) | VAF 41/1007 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2
- EXOC6B | c.183C>G p.D61E | Missense Mutation (SNP) | VAF 155/467 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FGF17 | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 295/1102 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- FSCN1 | c.919T>C p.F307L | Missense Mutation (SNP) | VAF 260/941 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSHR | c.1114A>T p.I372F | Missense Mutation (SNP) | VAF 149/480 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GCN1 | c.6949A>G p.R2317G | Missense Mutation (SNP) | VAF 189/481 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM6 | c.938C>A p.T313N | Missense Mutation (SNP) | VAF 314/629 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRM6 | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HSF1 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 186/1300 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- ICE1 | c.3644T>A p.I1215K | Missense Mutation (SNP) | VAF 138/339 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- IL17D | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 414/514 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- INO80 | c.4063A>T p.S1355C | Missense Mutation (SNP) | VAF 113/291 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IRF3 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 385/644 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ISL1 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 48/702 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2
- ITGA11 | c.2654A>T p.E885V | Missense Mutation (SNP) | VAF 142/321 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.315); called by mutect2, varscan2
- JMJD1C | c.1576T>C p.S526P | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); called by muse, mutect2
- KCNF1 | c.922T>G p.S308A | Missense Mutation (SNP) | VAF 219/974 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- KIZ | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KLHL38 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 172/1169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KMT2C | c.10795G>T p.E3599* | Nonsense Mutation (SNP) | VAF 284/438 reads (65%) | called by muse, mutect2, varscan2
- LAMB3 | c.3054T>G p.V1018= | Splice Region (SNP) | VAF 13/244 reads (5%) | called by muse, mutect2
- LOXHD1 | c.3150G>C p.E1050D | Missense Mutation (SNP) | VAF 331/585 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- LRRC4B | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 311/622 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MARS1 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 78/482 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAST4 | c.3541A>C p.S1181R (on ENST00000403625 / NM_001164664.2; = p.S992R on NM_015183.3) | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MATN1 | c.88T>A p.S30T | Missense Mutation (SNP) | VAF 180/492 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MMRN2 | c.2126A>C p.K709T | Missense Mutation (SNP) | VAF 300/672 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPPED1 | c.747G>T p.L249= | Splice Region (SNP) | VAF 278/281 reads (99%) | called by muse, mutect2, varscan2
- MYH6 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 20/517 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- MYO3B | c.1771A>T p.I591F | Missense Mutation (SNP) | VAF 97/289 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NAV2 | c.6229C>G p.L2077V (on ENST00000396087 / NM_001244963.2; = p.L2018V on NM_145117.5) | Missense Mutation (SNP) | VAF 123/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NRG3 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NSF | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR52D1 | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- OTUD3 | c.1197A>G p.*399Wext*19 | Nonstop Mutation (SNP) | VAF 133/301 reads (44%) | called by muse, mutect2, varscan2
- PAK5 | c.1474T>G p.F492V | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PCDHGB3 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 190/460 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PDPK1 | c.1543T>G p.F515V | Missense Mutation (SNP) | VAF 225/469 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PI15 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 125/704 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG5 | c.2311T>A p.S771T (on ENST00000400915 / NM_001042663.3; = p.S734T on NM_020631.6) | Missense Mutation (SNP) | VAF 285/922 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRR19 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 200/270 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PZP | c.4055A>T p.Q1352L | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2
- RALGAPA1 | c.2912T>A p.L971H | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); called by muse, mutect2
- RASA2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 92/364 reads (25%) | called by muse, mutect2, varscan2
- RFX1 | c.610T>A p.S204T | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.931); called by muse, varscan2
- ROBO3 | c.1916A>C p.E639A | Missense Mutation (SNP) | VAF 160/446 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SEC24B | c.2041T>G p.L681V | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.161); called by muse, mutect2
- SH3TC2 | c.535T>G p.F179V | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SHISA6 | c.1172C>A p.S391Y (on ENST00000409168 / NM_001173461.1; = p.S442Y on NM_207386.4) | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC9B1 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SLCO1B3 | c.1099T>C p.Y367H | Missense Mutation (SNP) | VAF 53/1430 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLITRK3 | c.1709T>C p.L570P | Missense Mutation (SNP) | VAF 28/532 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- SNCG | c.298T>A p.L100M | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SPA17 | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- STING1 | c.967T>G p.F323V | Missense Mutation (SNP) | VAF 102/589 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- STOX1 | c.2381T>C p.L794P | Missense Mutation (SNP) | VAF 159/407 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SZT2 | c.7447_7448del p.S2483Cfs*8 (on ENST00000634258 / NM_001365999.1; = p.S2426Cfs*8 on NM_015284.4) | Frame Shift Del (DEL) | VAF 364/811 reads (45%) | called by pindel, varscan2
- TBL1XR1 | c.1114A>C p.T372P | Missense Mutation (SNP) | VAF 69/576 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- TJP2 | c.621A>C p.Q207H | Missense Mutation (SNP) | VAF 316/829 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- TNIK | c.3421T>A p.L1141M | Missense Mutation (SNP) | VAF 95/793 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- TRIM49 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- USH2A | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- VAMP7 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 185/446 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- YTHDF2 | c.1045A>C p.T349P | Missense Mutation (SNP) | VAF 193/507 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZDHHC22 | c.528A>T p.G176= | Splice Region (SNP) | VAF 121/273 reads (44%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7532A>T p.H2511L | Missense Mutation (SNP) | VAF 385/958 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF431 | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF613 | c.461C>T p.S154F (on ENST00000293471 / NM_001031721.4; = p.S118F on NM_024840.4) | Missense Mutation (SNP) | VAF 157/158 reads (99%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCK5 | c.1077G>A p.S359= | Silent (SNP) | VAF 230/1010 reads (23%) | catalogued as rs782110176, COSV58233831; called by muse, mutect2, varscan2
- ASH1L | c.2523G>T p.G841= | Silent (SNP) | VAF 127/320 reads (40%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.672T>C p.T224= | Silent (SNP) | VAF 204/938 reads (22%) | called by muse, mutect2, varscan2
- BCR | c.2979C>T p.S993= | Silent (SNP) | VAF 140/569 reads (25%) | called by muse, mutect2, varscan2
- CCDC24 | c.918A>G p.P306= | Silent (SNP) | VAF 148/562 reads (26%) | called by muse, mutect2, varscan2
- COL11A1 | c.4038T>C p.P1346= | Silent (SNP) | VAF 117/241 reads (49%) | called by muse, mutect2, varscan2
- CTNNAL1 | c.1857T>C p.T619= | Silent (SNP) | VAF 60/172 reads (35%) | called by muse, mutect2, varscan2
- DCP1B | c.84C>T p.I28= | Silent (SNP) | VAF 43/306 reads (14%) | called by muse, mutect2, varscan2
- DENND4B | c.414C>T p.P138= | Silent (SNP) | VAF 249/627 reads (40%) | catalogued as rs752945372; called by muse, mutect2, varscan2
- FCRL3 | c.1212T>C p.C404= | Silent (SNP) | VAF 130/263 reads (49%) | called by muse, mutect2, varscan2
- FZR1 | c.21G>C p.R7= | Silent (SNP) | VAF 248/248 reads (100%) | called by muse, mutect2, varscan2
- GRIN3B | c.675A>G p.P225= | Silent (SNP) | VAF 366/806 reads (45%) | catalogued as rs1336913851; called by muse, mutect2, varscan2
- KCNT2 | c.981C>T p.L327= | Silent (SNP) | VAF 63/221 reads (29%) | catalogued as rs756536646; called by muse, mutect2, varscan2
- KIF7 | c.2586C>T p.R862= | Silent (SNP) | VAF 173/374 reads (46%) | catalogued as rs141097070; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KLHL14 | c.1038C>T p.D346= | Silent (SNP) | VAF 125/471 reads (27%) | catalogued as rs780531893, COSV63830298; called by muse, mutect2, varscan2
- LRRC6 | c.250T>C p.L84= | Silent (SNP) | VAF 51/416 reads (12%) | catalogued as rs750250466; called by muse, mutect2, varscan2
- LYAR | c.774C>T p.S258= | Silent (SNP) | VAF 229/484 reads (47%) | catalogued as rs781568883; called by muse, mutect2, varscan2
- MOB2 | c.157C>T p.L53= | Silent (SNP) | VAF 33/670 reads (5%) | catalogued as rs1266745885; called by muse, mutect2
- MRPS15 | c.135C>T p.L45= | Silent (SNP) | VAF 210/495 reads (42%) | catalogued as rs748086571; called by muse, mutect2, varscan2
- NEDD4L | c.2721A>C p.R907= (on ENST00000400345 / NM_001144967.3; = p.R887= on NM_015277.6) | Silent (SNP) | VAF 560/740 reads (76%) | called by muse, mutect2, varscan2
- NET1 | c.1239T>C p.T413= (on ENST00000355029 / NM_001047160.3; = p.T359= on NM_005863.5) | Silent (SNP) | VAF 112/130 reads (86%) | called by muse, varscan2
- NYNRIN | c.3276C>T p.T1092= | Silent (SNP) | VAF 275/533 reads (52%) | catalogued as rs371702363; called by muse, mutect2, varscan2
- PGBD5 | c.90C>T p.D30= | Silent (SNP) | VAF 110/419 reads (26%) | catalogued as rs1269287672; called by muse, mutect2, varscan2
- PRAMEF14 | c.18A>T p.P6= | Silent (SNP) | VAF 22/458 reads (5%) | called by muse, mutect2
- PTGES3L-AARSD1 | c.1161T>C p.T387= (on ENST00000421990 / NM_001136042.2; = p.T369= on NM_025267.3) | Silent (SNP) | VAF 110/292 reads (38%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.624A>C p.R208= | Silent (SNP) | VAF 288/741 reads (39%) | called by muse, mutect2, varscan2
- RANBP10 | c.588C>T p.L196= | Silent (SNP) | VAF 101/293 reads (34%) | catalogued as rs1212480444; called by muse, mutect2, varscan2
- SAMD9L | c.1782A>G p.L594= | Silent (SNP) | VAF 141/457 reads (31%) | called by muse, mutect2, varscan2
- SCN10A | c.4917C>T p.D1639= | Silent (SNP) | VAF 211/436 reads (48%) | catalogued as rs142804903; called by muse, mutect2, varscan2
- SHROOM2 | c.4632C>T p.D1544= | Silent (SNP) | VAF 214/215 reads (100%) | catalogued as rs200352588, COSV66606921; called by muse, mutect2, varscan2
- SLC4A4 | c.2538C>A p.V846= (on ENST00000264485 / NM_001098484.3; = p.V802= on NM_003759.4) | Silent (SNP) | VAF 139/379 reads (37%) | called by muse, varscan2
- SLC52A2 | c.75T>C p.A25= | Silent (SNP) | VAF 434/1365 reads (32%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.495T>C p.F165= | Silent (SNP) | VAF 74/185 reads (40%) | catalogued as rs751725192; called by muse, mutect2, varscan2
- TBC1D17 | c.486C>T p.R162= | Silent (SNP) | VAF 306/657 reads (47%) | catalogued as rs1444774989; called by muse, mutect2, varscan2
- TGFBRAP1 | c.186G>A p.T62= | Silent (SNP) | VAF 152/649 reads (23%) | called by muse, mutect2, varscan2
- TRAF1 | c.1248T>A p.T416= | Silent (SNP) | VAF 101/249 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.2034T>A p.T678= (on ENST00000591111; = p.T632= on NM_003319.4) | Silent (SNP) | VAF 58/260 reads (22%) | called by muse, mutect2, varscan2
- ZNF431 | c.804T>G p.A268= | Silent (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- ZNF638 | c.714C>T p.V238= | Silent (SNP) | VAF 28/606 reads (5%) | catalogued as rs113179624; called by muse, mutect2
- ARHGEF1 | c.*258A>C | 3'UTR (SNP) | VAF 209/550 reads (38%) | called by muse, mutect2, varscan2
- DIRC1 | n.368C>T | RNA (SNP) | VAF 335/570 reads (59%) | catalogued as rs538669584; called by muse, mutect2, varscan2
- EPB41L3 | c.2350-1237A>G | Intron (SNP) | VAF 66/214 reads (31%) | called by muse, mutect2, varscan2
- INSRR | c.3397+29G>A | Intron (SNP) | VAF 146/342 reads (43%) | catalogued as rs777227609, COSV63870785; called by muse, mutect2, varscan2
- LMO7DN | n.116G>A | RNA (SNP) | VAF 118/276 reads (43%) | called by muse, varscan2
- SYCE1 | chr10:133554289 T>A | 3'Flank (SNP) | VAF 130/337 reads (39%) | called by muse, mutect2, varscan2
- UMOD | c.89-601G>A | Intron (SNP) | VAF 119/328 reads (36%) | catalogued as rs776436785; called by muse, mutect2, varscan2
